Somatic mutation profile of tumor specimen TCGA-2J-AABA-01A (aliquot TCGA-2J-AABA-01A-21D-A40W-08) from TCGA case TCGA-2J-AABA, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 55.1 years (20,133 days).
Specimen TCGA-2J-AABA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27320e1b-e676-4152-b88b-2e9487f56570.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AABA-10A (Blood Derived Normal), aliquot TCGA-2J-AABA-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23441b6c-aff3-4344-a61d-cc8a57d2017c

The open-access MAF lists 32 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 18, Frame Shift Del 5, Silent 4, Nonsense Mutation 3, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1527G>A p.W509* | Nonsense Mutation (SNP) | VAF 57/323 reads (18%) | catalogued as rs377767370, CM086965, COSV100747876, COSV61689637; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACCS | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV99773026; called by muse, mutect2, varscan2
- ARID1A | c.4624G>T p.E1542* | Nonsense Mutation (SNP) | VAF 42/229 reads (18%) | catalogued as COSV61371858, COSV61383029; called by muse, mutect2, varscan2
- CMYA5 | c.4478A>G p.D1493G | Missense Mutation (SNP) | VAF 89/678 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV101484447; called by muse, mutect2, varscan2
- DNMT3A | c.2410C>T p.P804S | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV53036301; called by muse, mutect2, varscan2
- EPHA7 | c.2108G>A p.R703K | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.872); catalogued as COSV100994457, COSV65176953; called by muse, mutect2, varscan2
- FBXW7 | c.2018G>A p.W673* (on ENST00000281708 / NM_001349798.2; = p.W593* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 97/793 reads (12%) | catalogued as COSV55899831, COSV55912740, COSV99661744; called by muse, mutect2, varscan2
- HOXA4 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 89/544 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200302499; called by muse, mutect2, varscan2
- INTS1 | c.3665G>A p.R1222H | Missense Mutation (SNP) | VAF 67/327 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs370023670; called by muse, mutect2, varscan2
- IQCF2 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 67/537 reads (12%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.96); catalogued as COSV100291120; called by muse, mutect2, varscan2
- JAKMIP1 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs1366592247, COSV99288971; called by muse, mutect2, varscan2
- KIDINS220 | c.3118G>T p.V1040L | Missense Mutation (SNP) | VAF 57/398 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.063); catalogued as COSV56751209; called by muse, mutect2, varscan2
- MOGS | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 58/429 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.957); catalogued as rs776932912, COSV99270856; called by muse, mutect2, varscan2
- NCAPH | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 94/728 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV99546308; called by muse, mutect2, varscan2
- NCKAP5 | c.3010A>G p.I1004V | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs763895019, COSV100494738; called by muse, mutect2, varscan2
- PAWR | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 52/332 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.295); catalogued as COSV100174459; called by muse, mutect2, varscan2
- RIMS2 | c.4550A>C p.K1517T (on ENST00000666250 / NM_001348490.2; = p.K1088T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99212255; called by muse, mutect2
- STRIP2 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 74/397 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV99974248; called by muse, mutect2, varscan2
- TMEM37 | c.520del p.L174* | Frame Shift Del (DEL) | VAF 177/1140 reads (16%) | catalogued as COSV50028929; called by mutect2, pindel, varscan2
- TTN | c.74069G>A p.R24690Q (on ENST00000591111; = p.R17266Q on NM_003319.4) | Missense Mutation (SNP) | VAF 96/512 reads (19%) | PolyPhen probably damaging (0.996); catalogued as rs758190406, COSV60188912; called by muse, mutect2, varscan2
- WRN | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 51/339 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375762379; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF28 | c.627C>G p.H209Q | Missense Mutation (SNP) | VAF 81/694 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV100354831; called by muse, mutect2, varscan2
- ACTB | c.29_31del p.V10del | In Frame Del (DEL) | VAF 36/258 reads (14%) | called by pindel, varscan2
- AFDN | c.1525del p.A509Qfs*9 | Frame Shift Del (DEL) | VAF 26/199 reads (13%) | called by mutect2, pindel, varscan2
- APOB | c.13225_13228del p.S4409* | Frame Shift Del (DEL) | VAF 35/276 reads (13%) | called by pindel, varscan2
- CEACAM20 | c.1427_1427+5del p.X476_splice | Splice Site (DEL) | VAF 22/104 reads (21%) | called by mutect2, varscan2
- GTF3C3 | c.2216del p.N739Mfs*35 | Frame Shift Del (DEL) | VAF 44/259 reads (17%) | called by mutect2, pindel, varscan2
- PMEPA1 | c.664_682del p.G222Rfs*42 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | called by mutect2, pindel
- BLVRA | c.9A>T p.A3= | Silent (SNP) | VAF 50/288 reads (17%) | catalogued as COSV99646157; called by muse, mutect2
- MUC2 | c.4020G>A p.S1340= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as rs993156242; called by muse, mutect2, varscan2
- NEBL | c.498C>T p.D166= | Silent (SNP) | VAF 63/341 reads (18%) | catalogued as rs371105861; ClinVar: likely benign; called by muse, mutect2, varscan2
- QRFPR | c.522C>T p.V174= | Silent (SNP) | VAF 173/995 reads (17%) | catalogued as rs1300875072, COSV100543998; called by muse, mutect2, varscan2
